Somatic mutation profile of tumor specimen 0DJR0U from CCDI case PBBXFV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Nasopharynx, NOS; Age at diagnosis: 4.3 years (1,555 days).
Specimen 0DJR0U: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75f3adf0-d716-4820-a9c3-df6b0a436f07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJQZE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c87fab0-80bf-4d0d-9338-ac57d6a41115

The open-access MAF lists 34 somatic variants for this specimen: 23 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Intron 3, Splice Site 2, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALB | c.1012G>T p.D338Y | Missense Mutation (SNP) | VAF 260/620 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV55736203; called by mutect2, varscan2
- ANKS1B | c.587C>T p.T196M | Missense Mutation (SNP) | VAF 347/1143 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749925621, COSV61343978; called by muse, mutect2, varscan2
- ATP2A1 | c.2749T>C p.S917P | Missense Mutation (SNP) | VAF 74/165 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62869525; called by muse, mutect2, varscan2
- DNAH14 | c.6061dup p.T2021Nfs*12 (on ENST00000445597; = p.T2674Nfs*12 on NM_001367479.1) | Frame Shift Ins (INS) | VAF 287/636 reads (45%) | catalogued as rs777044353; called by mutect2, varscan2
- GABRG2 | c.512G>T p.R171I | Missense Mutation (SNP) | VAF 340/813 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV62721846; called by muse, mutect2, varscan2
- HECA | c.1342G>A p.V448M | Missense Mutation (SNP) | VAF 216/553 reads (39%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.998); catalogued as rs1446355948; called by muse, mutect2, varscan2
- IL6R | c.212C>A p.P71H | Missense Mutation (SNP) | VAF 84/182 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100691104, COSV59818040; called by muse, mutect2, varscan2
- NRXN1 | c.3443G>A p.R1148Q | Missense Mutation (SNP) | VAF 323/1161 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV100452654, COSV58460250; called by muse, mutect2, varscan2
- OR2G2 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 233/520 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs200433328, COSV60740485; called by muse, mutect2, varscan2
- PLSCR5 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 237/894 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1219239992; called by muse, varscan2
- POTEH | c.1166+1G>A p.X389_splice | Splice Site (SNP) | VAF 47/867 reads (5%) | catalogued as rs767034676; called by muse, mutect2
- TBX4 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 190/868 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.333); catalogued as COSV53609019; called by muse, mutect2, varscan2
- UNC5D | c.1919A>G p.Q640R | Missense Mutation (SNP) | VAF 188/1158 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.341); catalogued as COSV54843025; called by muse, mutect2, varscan2
- GPR139 | c.598T>C p.F200L | Missense Mutation (SNP) | VAF 109/220 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MDN1 | c.13740G>C p.E4580D | Missense Mutation (SNP) | VAF 324/715 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.883); called by muse, varscan2
- MKI67 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 211/533 reads (40%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- MTREX | c.2938G>A p.A980T | Missense Mutation (SNP) | VAF 194/535 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- NLGN1 | c.1640C>T p.A547V | Missense Mutation (SNP) | VAF 186/681 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.481); called by muse, mutect2, varscan2
- NTN5 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 225/355 reads (63%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- POTEM | c.1055+1G>A p.X352_splice | Splice Site (SNP) | VAF 32/540 reads (6%) | called by muse, mutect2
- PTK7 | c.1192G>T p.G398C | Missense Mutation (SNP) | VAF 258/573 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB19 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 235/816 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SLC16A7 | c.804G>C p.L268F | Missense Mutation (SNP) | VAF 249/803 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- DCT | c.498G>T p.L166= | Silent (SNP) | VAF 150/686 reads (22%) | called by muse, mutect2, varscan2
- DNAH11 | c.10779G>A p.K3593= | Silent (SNP) | VAF 52/1458 reads (4%) | catalogued as COSV60945041; called by muse, mutect2
- EML5 | c.2706T>C p.H902= | Silent (SNP) | VAF 216/585 reads (37%) | called by muse, mutect2, varscan2
- MAP2 | c.861C>A p.G287= | Silent (SNP) | VAF 191/963 reads (20%) | called by muse, mutect2, varscan2
- NBPF12 | c.2526T>A p.P842= | Silent (SNP) | VAF 55/140 reads (39%) | called by muse, mutect2, varscan2
- RIIAD1 | c.111G>A p.K37= | Silent (SNP) | VAF 186/440 reads (42%) | called by muse, mutect2, varscan2
- SIVA1 | c.90C>T p.C30= | Silent (SNP) | VAF 80/174 reads (46%) | catalogued as rs763281046; called by muse, mutect2, varscan2
- HLTF | c.2377-70A>C | Intron (SNP) | VAF 106/344 reads (31%) | called by muse, mutect2, varscan2
- PABPC3 | c.-21C>A | 5'UTR (SNP) | VAF 44/148 reads (30%) | called by muse, mutect2, varscan2
- SMARCE1 | c.816+58C>T | Intron (SNP) | VAF 211/234 reads (90%) | called by muse, mutect2, varscan2
- UTP6 | c.544-27G>T | Intron (SNP) | VAF 132/400 reads (33%) | catalogued as COSV55575969; called by muse, mutect2, varscan2
